Somatic mutation profile of tumor specimen TCGA-AA-3521-01A (aliquot TCGA-AA-3521-01A-01D-1953-10) from TCGA case TCGA-AA-3521, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage II; Age at diagnosis: 87.1 years (31,805 days).
Specimen TCGA-AA-3521-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1a9a5a65-d4db-486e-88a9-fdbb53f0a6f5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3521-11A (Solid Tissue Normal), aliquot TCGA-AA-3521-11A-01D-1554-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aeb6f447-4ca2-439d-8f8a-1aede4b645ba

The open-access MAF lists 16 somatic variants for this specimen: 13 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 10, Silent 3, Splice Site 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCDC116 | c.415C>T p.R139W | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as rs763382560, COSV53039046; called by muse, mutect2, varscan2
- EXOC3L2 | c.2279G>A p.R760H | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.514); catalogued as rs749294188, COSV99374485; called by muse, mutect2, varscan2
- FBXW5 | c.1636G>A p.V546I | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs771667923, COSV56402422; called by muse, mutect2, varscan2
- KCNA4 | c.673C>T p.R225C | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60252247; called by muse, mutect2, varscan2
- KCNC3 | c.2054T>C p.M685T | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV100979211; called by muse, mutect2, varscan2
- KDM7A | c.281-1G>C p.X94_splice | Splice Site (SNP) | VAF 13/191 reads (7%) | catalogued as COSV99134118; called by muse, mutect2
- KIFC2 | c.1324C>T p.R442C | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs781565567, COSV100023614; called by muse, mutect2, varscan2
- LAMA5 | c.5578C>T p.R1860* | Nonsense Mutation (SNP) | VAF 129/392 reads (33%) | catalogued as rs913476212, COSV99438916; called by muse, mutect2, varscan2
- OTOF | c.2360G>A p.R787H (on ENST00000272371 / NM_194248.3; = p.R40H on NM_004802.4) | Missense Mutation (SNP) | VAF 49/59 reads (83%) | SIFT tolerated (0.25); PolyPhen benign (0.138); catalogued as rs867139017, COSV99717095; called by muse, mutect2, varscan2
- PRDM9 | c.525G>T p.E175D | Missense Mutation (SNP) | VAF 113/206 reads (55%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as COSV99690136; called by muse, varscan2
- TMF1 | c.3214G>T p.D1072Y | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101275416; called by muse, mutect2, varscan2
- WSCD2 | c.1210G>A p.G404S | Missense Mutation (SNP) | VAF 48/210 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.076); catalogued as rs1379043488, COSV54578928; called by muse, mutect2, varscan2
- TRPS1 | c.3133del p.S1045Vfs*24 (on ENST00000220888 / NM_001330599.2; = p.S1058Vfs*24 on NM_014112.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 64/233 reads (27%) | called by mutect2, pindel, varscan2
- CHRNA4 | c.1278C>T p.S426= | Silent (SNP) | VAF 44/77 reads (57%) | catalogued as rs202169925, COSV100937383; ClinVar: likely benign; called by muse, mutect2, varscan2
- LAMP1 | c.759A>C p.T253= | Silent (SNP) | VAF 121/739 reads (16%) | catalogued as COSV100208544; called by muse, mutect2, varscan2
- PAPPA2 | c.801G>A p.G267= | Silent (SNP) | VAF 48/138 reads (35%) | catalogued as COSV100866687; called by muse, mutect2, varscan2
